Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01R, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01R-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

This is a poorly differentiated mucinous adenocarcinoma of the ascending colon with a histopathological grade G3 differentiation, with necroses, with peritumorous chronic recurrent concomitant inflammation, with ulcerations of the inner tumor surface, with carcinomatous lymphangiosis, with tumor infiltration in the layers of the colon wall as far as the pericolic fatty connective tissue, with nine regional lymph node metastases (9/19), tumor-free overview sections from the resection margins and from the reticular fatty tissue, and also chronic appendicitis.

According to these prepared sections, the tumor spread of the colon carcinoma corresponds to the tumor stage pT3, pN2, MX, L1, R0

11+

1CD-0-3

Adenocarcinoma, mucinous, NOS 8480/3
Site: ascending colon C18.2 hr 3/30/11

Diagnostic Discrepancy		
PIPA Discrepancy		

KMI
5/16/11

Source: NCI Genomic Data Commons file ef8e348f-89ee-4e30-8a6f-5f008d08c7ba (TCGA-AA-A01R.DD52773D-8352-4DD1-84FC-8C9BABB9C5AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).